Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3MW, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3MW-01A (Primary Tumor).

Surgical Pathology Report

Department of Pathology,

DOB:

Sex: F

Physician:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:

FOLLICULAR VARIANT OF PAPILLARY THYROID CARCINOMA (1.5 CM), RIGHT LOBE.

Adenomatous nodules, left lobe.

One lymph node, no tumor present (0/1).

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A product of total thyroidectomy with overall measurements of 8.0 x 3.5 x 1.8 cm. The right lobe is slightly enlarged, nodular, and measures 3.5 x 3.0 x 1.8 cm. The left lobe is unremarkable and measures 3.5 x 1.5 x 0.8 cm. On sectioning multiple well-circumscribed nodules ranging in size from 0.3-1.5 cm are noted in the superior middle lower lobe. The largest nodule is 1.5 x 1.5 x 2.3 cm. The isthmus and the left lobe on sectioning are unremarkable.

SECTION CODE: A1-A6, sequential sectioning of the right lobe from superior to inferior including the nodules; A7, representative section of the isthmus; A8-A13, sequential sectioning of the left lobe from superior to inferior.

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, T-C4200, M-83403

ICD-0-3

(707)

Path: carcinoma, papillary, follicular variant 8340/3

CQCF: carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

hw
1/7/12

Released by:

Surgical Pathology Report	Page 1 of 1
File under: Pathology	

Source: NCI Genomic Data Commons file 67e7b374-e51d-4614-8cb7-5dfcd69215ba (TCGA-EL-A3MW.FCDCD4CD-0F6C-457D-A670-E7FFB4ED3495.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).